Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-AA68, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-AA68-01A (Primary Tumor).

[page 1 of 2]
Collect date

ICD-O-3
Adenocarcinoma, tubular
8211.3
Site: gastroesophageal junction
C16.0
JW 8/20/14

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Gastroesophageal junction)

- Product of gastrectomy:

Adenocarcinoma characterized as follows:

Location: esophagogastric transition

Histological pattern(s) observed:

Tubular

Histologic Grade II - moderately differentiated

Intestinal type of Lauren's Classification

Measure the longest axis of the tumor: 4.8

Ulceration:

Present

Involvement of:

Adjacent adipose tissue

Type of tumor invasion

Spiculated

Inflammatory reaction:

Moderate

Tumor implantation in peri-visceral adipose tissue: not detected

Proximal margin.

Free of neoplastic involvement.

Distal margin.

Free of neoplastic involvement.

Neural infiltration:

Present

Lymphatic vascular invasion:

Present

Sanguineous vascular invasion:

Not detected

Greater omentum:

Free of neoplastic involvement.

Discrimination of lymph nodes according to the standardization, JGCA - 1998

(compromised / dissected lymph nodes ratio:)

F - Chain 1 - right paracardiac (7/ 10)

G - Chain 2 - left paracardiac: Connective tissue free of cancer

H - Chain 3 - along the lesser curvature: (3/5)

L - Chain 5 - suprapyloric: connective tissue free of neoplasm

N - Chain 7 - along the left gastric artery: (3/3)

Q - Chain 9 - around the celiac trunk: (3/3)

[page 2 of 2]
S - Chain 11p - along the proximal splenic artery: (2/2)

AJ - Chain 110 – inferior para-esophageal: (0/1)

- Hepato - gastric ligament (AM1/AM2) - Connective tissue free of cancer.

Lymph nodes from the left renal vein and artery (AN1/AN2) : Metastasis of adenocarcinoma with capsular transposition (3/3)

Esophageal margin (separately):

Absence of neoplasia.

Source: NCI Genomic Data Commons file 4504417a-9d43-4c40-811d-46bba69affa3 (TCGA-VQ-AA68.ADA7C2CA-8F8C-42EF-8904-A50E064424B2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).